Somatic mutation profile of tumor specimen 0DM8UB from CCDI case PBBZZA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Craniopharyngioma; Tissue or organ of origin: Brain stem; Age at diagnosis: 15.4 years (5,634 days).
Specimen 0DM8UB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7623596-a026-459f-a3d1-fc6bf73f8d66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM8U3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a17ebc35-cfe2-4a7f-986b-c02b9ba6df82

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, In Frame Del 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 205/824 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ST14 | c.2563G>A p.V855I | Missense Mutation (SNP) | VAF 127/593 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.138); catalogued as rs1470386225; called by muse, mutect2, varscan2
- TLL1 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 26/968 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs973789645; called by muse, mutect2
- CTNNB1 | c.85_98delinsAA p.S29_S33delinsN | In Frame Del (DEL) | VAF 209/797 reads (26%) | called by pindel, varscan2*
- ELP6 | c.323+36G>A | Intron (SNP) | VAF 79/297 reads (27%) | catalogued as rs1317223642; called by muse, mutect2, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 8/108 reads (7%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
